Gene-level copy-number profile of tumor specimen TCGA-AR-A1AH-01A from TCGA case TCGA-AR-A1AH, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 52.0 years (18,991 days).
Specimen TCGA-AR-A1AH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.1d7e40a7-9af9-45db-9586-9f8a3f6a1824.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A1AH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cb3916f4-37ea-4686-98da-26e09e344c1f

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 139; copy number 2: 41; copy number 3: 24,260; copy number 4: 160; copy number 5: 2,336; copy number 6: 26,496; copy number 7: 2,426; copy number 8: 100; copy number 9: 869; copy number 10: 1,021; copy number 11: 195; copy number 12: 25; copy number 13: 1,166; copy number 15: 39; copy number 16: 66; copy number 17: 69; copy number 18: 61; copy number 19: 78; copy number 20: 9; copy number 22: 65; copy number 24: 25; copy number 25: 45; copy number 27: 14; copy number 29: 63; copy number 35: 2; copy number 37: 17; copy number 38: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A1AH-01A-11D-A12A-01): tumor purity 0.85, ploidy 1.71, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:37,915,898–38,069,227, 1 gene (within-gene range 0–3): SHB.
- chr9:38,147,428–38,147,561, 1 gene: U8.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 1,743 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,055,033–3,885,429, 137 genes, copy number 13 (within-gene range 6–13) (broad region; genes not listed).
- chr1:37,566,816–38,965,038, 47 genes, copy number 13 (within-gene range 3–13): GNL2, AL513220.1, RSPO1, C1orf109, CDCA8, EPHA10, Y_RNA, ACTN4P2, AL929472.1, MANEAL, AL929472.3, YRDC, C1orf122, MTF1, AL929472.4, AL929472.2, INPP5B, SNORA63, RNU6-584P, Metazoa_SRP, SF3A3, RNU6-510P, FHL3, UTP11, POU3F1, MIR3659HG, AL139158.1, MIR3659, LINC02786, AL390839.1, AL390839.2, LINC01343, AL513479.1, RNU6-753P, LINC01685, HSPA5P1, AL354702.1, RRAGC, AL139260.2, AL139260.1, MYCBP, AL139260.3, GJA9, RHBDL2, RNU6-605P, Y_RNA, EIF1P2.
- chr1:43,933,320–67,833,467, 527 genes, copy number 13–24 (broad region; genes not listed).
- chr1:68,242,474–96,584,727, 429 genes, copy number 13–17 (broad region; genes not listed).
- chr1:118,883,046–121,580,524, 78 genes, copy number 19 (broad region; genes not listed).
- chr2:2,319,232–7,450,544, 64 genes, copy number 17–29 (broad region; genes not listed).
- chr2:7,922,425–15,942,249, 129 genes, copy number 22–37 (broad region; genes not listed).
- chr12:19,404,045–31,073,847, 192 genes, copy number 13–38 (within-gene range 4–38) (broad region; genes not listed).
- chr12:31,671,142–31,959,316, 12 genes, copy number 16 (within-gene range 3–16): AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1.
- chr12:32,679,200–34,166,954, 28 genes, copy number 16: DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1, YARS2, AC084824.3, AC084824.4, AC087588.2, PKP2, AC087588.1, RPL35AP27, ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4.
- chr12:37,575,587–42,717,120, 71 genes, copy number 15–35 (broad region; genes not listed).
- chr12:123,918,660–123,972,831, 1 gene, copy number 13 (within-gene range 10–13): CCDC92.
- chr12:123,960,717–124,882,668, 28 genes, copy number 13: AC068790.7, AC068790.4, AC068790.3, AC068790.2, AC068790.5, AC068790.6, ZNF664, AC068790.8, RFLNA, AC068790.1, AC068790.9, AC026358.1, NCOR2, MIR6880, AC073916.1, AC073592.1, AC073592.7, AC073592.3, AC073592.9, AC073592.5, AC073592.6, AC073592.8, AC073592.2, AC073592.10, AC073592.4, AC073593.1, SCARB1, AC073593.2.

Autosomal genes at a single copy (total copy number 1): 139. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
